Somatic mutation profile of tumor specimen MMRF_1519_1_BM_CD138pos (aliquot MMRF_1519_1_BM_CD138pos_T1_KBS5U_L02846) from MMRF case MMRF_1519, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 88.1 years (32,171 days).
Specimen MMRF_1519_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77a6bccb-e6fb-44b8-8b88-e2078fceb6cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1519_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1519_1_PB_Whole_C3_KBS5U_L02858; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c948550c-6059-47af-a814-2d3d3a098125

The open-access MAF lists 320 somatic variants for this specimen: 116 protein-altering or splice-affecting, 31 silent, 173 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, 3'UTR 93, Intron 34, Silent 31, 5'UTR 18, 5'Flank 10, 3'Flank 9, RNA 9, Nonsense Mutation 6, In Frame Del 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG2 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); catalogued as rs797044959, CM1412912, COSV61828039; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 19/103 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCC6 | c.2843T>A p.L948H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as CM153338; called by muse, mutect2, varscan2
- ADORA1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.155); catalogued as rs1183961544; called by muse, mutect2, varscan2
- AHRR | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as rs202003342; called by muse, mutect2, varscan2
- ANKRD30A | c.4174G>A p.A1392T (on ENST00000611781; = p.A1336T on NM_052997.2) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs201764363; called by muse, mutect2, varscan2
- ARHGEF28 | c.4960T>G p.S1654A (on ENST00000426542; = p.S1680A on NM_001080479.2) | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV104383030, COSV55257677; called by muse, varscan2
- BARHL2 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.959); catalogued as rs150916366, COSV64980840; called by muse, mutect2, varscan2
- CBX2 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1442198097, COSV99490745; called by muse, mutect2, varscan2
- CDC73 | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66468106; called by muse, mutect2, varscan2
- CEP162 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.077); catalogued as rs1373293630; called by muse, mutect2, varscan2
- CEP192 | c.3214A>G p.T1072A | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV58071995; called by muse, mutect2, varscan2
- COL6A1 | c.2134G>T p.D712Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1334833248; called by muse, mutect2, varscan2
- CPA4 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 71/336 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.402); catalogued as rs1399885810; called by muse, mutect2, varscan2
- CXCR4 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 117/182 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1274871337; called by muse, mutect2, varscan2
- DCDC1 | c.4379C>A p.T1460N (on ENST00000597505 / NM_001367979.1; = p.T567N on NM_020869.3) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs369053352; called by muse, mutect2, varscan2
- DNAJC28 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 39/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200167967, COSV58721170; called by muse, mutect2
- DST | c.5939C>T p.T1980I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as rs1453768114; called by muse, mutect2, varscan2
- EMC10 | c.186C>T p.I62= | Splice Region (SNP) | VAF 10/74 reads (14%) | catalogued as rs371024737; called by muse, mutect2, varscan2
- ENDOD1 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.603); catalogued as rs765306783; called by muse, mutect2, varscan2
- FBN3 | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs776712443, COSV54473777; called by muse, mutect2, varscan2
- FGFR1 | c.442C>T p.R148C (on ENST00000447712 / NM_023110.3; = p.P148S on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs780153672, COSV58333225; called by muse, mutect2, varscan2
- GEMIN5 | c.1831G>A p.V611M | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374532509; called by muse, mutect2, varscan2
- GLCCI1 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56205279, COSV99780837; called by muse, mutect2, varscan2
- HMCN1 | c.5774G>A p.G1925E | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1460860616; called by muse, mutect2, varscan2
- HOXD12 | c.161C>A p.T54K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs1317032777; called by muse, mutect2, varscan2
- HPD | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768775184, COSV56641134; called by muse, mutect2, varscan2
- IGHV2-70 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368945949; called by muse, varscan2
- KIAA1549 | c.4625G>A p.R1542H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769427032, COSV54314850; called by muse, mutect2
- MST1R | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as rs763246446, CM164569, COSV99617951; called by muse, mutect2, varscan2
- MYO15A | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV52756314; called by muse, mutect2, varscan2
- NLRP5 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.57); catalogued as rs565332613, COSV66765011; called by muse, mutect2, varscan2
- NPAP1 | c.2724G>T p.Q908H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV100275108; called by muse, mutect2
- OR13C4 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV52928843; called by muse, mutect2, varscan2
- PCLO | c.4670G>A p.R1557Q | Missense Mutation (SNP) | VAF 310/426 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1424768942, COSV61616342, COSV61629128; called by muse, mutect2, varscan2
- PCLO | c.2657G>A p.G886D | Missense Mutation (SNP) | VAF 114/148 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV61673230; called by muse, mutect2, varscan2
- PLEKHG6 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.265); catalogued as rs758700820; called by muse, mutect2, varscan2
- PSMA1 | c.288A>T p.R96S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.247); catalogued as rs767000878; called by muse, mutect2, varscan2
- PTPRC | c.2671C>A p.Q891K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777458591; called by muse, mutect2, varscan2
- SSTR5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1287072636, COSV53512444; called by muse, mutect2, varscan2
- TCERG1 | c.2849T>C p.I950T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.452); catalogued as rs1325002572; called by muse, mutect2, varscan2
- TENM3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); catalogued as COSV69308441; called by muse, mutect2, varscan2
- TLR2 | c.1126T>C p.Y376H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.258); catalogued as rs1430645337; called by muse, mutect2, varscan2
- TNC | c.4063G>A p.V1355M | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs569664449, COSV60785672; called by muse, mutect2, varscan2
- TRHDE | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1300960136, COSV53845146; called by muse, mutect2, varscan2
- TXNIP | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs782132353; called by muse, mutect2, varscan2
- VIPR2 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as rs1020789513, COSV51112216; called by muse, mutect2
- ZNF462 | c.5253C>G p.D1751E | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.673); catalogued as rs146614277; called by muse, mutect2, varscan2
- A2M | c.4389C>A p.Y1463* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.3898C>A p.Q1300K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AFF2 | c.1589T>C p.L530P | Missense Mutation (SNP) | VAF 68/99 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APLF | c.413A>T p.H138L | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ATP7B | c.2371G>T p.A791S | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- AURKC | c.605C>T p.T202I (on ENST00000302804 / NM_001015878.2; = p.T168I on NM_003160.3) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRDT | c.1490T>C p.I497T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAMK2B | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2
- CDC42BPG | c.1529A>G p.Q510R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP91 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- CFH | c.2830C>A p.H944N | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLASP2 | c.3917T>A p.M1306K (on ENST00000359576; = p.M1305K on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CYSTM1 | c.229T>G p.S77A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- DCP1B | c.1297A>G p.T433A | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKI | c.2248T>G p.S750A | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- DGKI | c.1681A>T p.K561* | Nonsense Mutation (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- DIS3 | c.1556T>C p.L519S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNASE2B | c.488G>T p.R163I | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- E2F2 | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ENAM | c.3209C>T p.T1070I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FAM222B | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2, varscan2
- FLT1 | c.2106A>T p.Q702H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FRMPD1 | c.3961A>G p.M1321V | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- G6PC2 | c.758C>G p.T253S | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GLIPR1L2 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGB1 | c.8094_8099del p.E2699_T2700del | In Frame Del (DEL) | VAF 43/291 reads (15%) | called by pindel, varscan2
- GPX7 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- HERC5 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- HMCN1 | c.15801T>G p.N5267K | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3-53 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IRAK1BP1 | c.450T>A p.D150E | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KIR3DL3 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.199); called by muse, mutect2
- LAMB1 | c.2027C>A p.T676K | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2
- LCE5A | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LTBP1 | c.3065G>A p.C1022Y (on ENST00000404816 / NM_206943.4; = p.C696Y on NM_000627.4) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MUC1 | c.2986A>C p.S996R (on ENST00000611571 / NM_001371720.1; = p.S209R on NM_001204285.2) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MYO10 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2
- MYOC | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- MYRF | c.907C>T p.L303F (on ENST00000278836 / NM_001127392.3; = p.L294F on NM_013279.4) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- NRXN3 | c.1432A>G p.T478A (on ENST00000335750 / NM_001330195.2; = p.T105A on NM_004796.6) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR6V1 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PCDHGA11 | c.1161T>G p.I387M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PLD5 | c.385C>T p.H129Y (on ENST00000442594; = p.H67Y on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PLEKHA4 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | called by muse, varscan2
- PRKAR1B | c.745T>C p.F249L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PRMT3 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTCHD4 | c.2395T>G p.C799G | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PTPN14 | c.2759A>G p.K920R | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPRM | c.1330C>A p.H444N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- RANBP17 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RP1L1 | c.6653A>T p.E2218V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCFD2 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- SEMG2 | c.1577A>C p.K526T | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.062); called by muse, mutect2
- SLC2A2 | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- SLCO4C1 | c.803-1G>C p.X268_splice | Splice Site (SNP) | VAF 34/197 reads (17%) | called by muse, mutect2, varscan2
- SRD5A1 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SRD5A1 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- STON2 | c.2550G>T p.W850C (on ENST00000649389 / NM_001366849.2; = p.W793C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNGAP1 | c.1809G>A p.M603I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TTBK1 | c.2924C>T p.A975V | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP33 | c.2080G>T p.V694F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCPIP1 | c.3502G>T p.E1168* | Nonsense Mutation (SNP) | VAF 22/308 reads (7%) | called by muse, mutect2
- WDFY4 | c.4839G>C p.E1613D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.525); called by muse, mutect2
- WFDC13 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ZAN | c.4102T>G p.C1368G | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF396 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ZNF836 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZNF99 | c.740G>A p.C247Y | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.1764C>T p.A588= | Silent (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- B3GNT6 | c.852C>A p.G284= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- BASP1 | c.135C>T p.A45= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- CILP2 | c.99A>T p.A33= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- CSMD2 | c.1230A>G p.R410= | Silent (SNP) | VAF 36/105 reads (34%) | called by muse, mutect2, varscan2
- DUSP2 | c.252G>A p.E84= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs768266724, COSV56619478; called by muse, mutect2, varscan2
- FOXE1 | c.843C>T p.Y281= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1275774682; called by muse, mutect2
- FSIP2 | c.162G>A p.G54= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- GJD4 | c.639C>T p.L213= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs765570077, COSV58702235; called by muse, mutect2, varscan2
- GUCY2D | c.1311G>A p.P437= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs775635196, COSV54696534; called by muse, mutect2, varscan2
- IGHV2-70 | c.108C>G p.T36= | Silent (SNP) | VAF 24/24 reads (100%) | catalogued as rs371944329; called by muse, varscan2
- IGHV2-70 | c.87G>C p.A29= | Silent (SNP) | VAF 26/26 reads (100%) | catalogued as rs369078954; called by muse, varscan2
- INO80B | c.1038C>T p.P346= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as rs768194664; called by muse, mutect2, varscan2
- KHDC3L | c.345G>T p.A115= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs760286211; called by muse, mutect2, varscan2
- KLF9 | c.135G>A p.K45= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- MTSS1 | c.1929C>T p.H643= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs768990469; called by muse, mutect2, varscan2
- NECAP1 | c.204C>G p.L68= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs1199458103, COSV60248677; called by muse, mutect2, varscan2
- NGEF | c.852C>T p.S284= | Silent (SNP) | VAF 52/272 reads (19%) | catalogued as rs755831802, COSV50914046; called by muse, mutect2, varscan2
- NLRP8 | c.699C>T p.Y233= | Silent (SNP) | VAF 40/221 reads (18%) | catalogued as rs377108884; called by muse, mutect2, varscan2
- OR4B1 | c.237C>T p.F79= | Silent (SNP) | VAF 17/191 reads (9%) | catalogued as COSV58882085; called by muse, mutect2
- PCDH12 | c.1296C>G p.A432= | Silent (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- PLXNA2 | c.3189C>A p.G1063= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- PTPRE | c.792G>A p.E264= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs767743192; called by muse, mutect2, varscan2
- SERPINB3 | c.840C>T p.V280= | Silent (SNP) | VAF 20/183 reads (11%) | called by muse, mutect2, varscan2
- SRP9 | c.9G>A p.Q3= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2
- STEAP3 | c.327G>A p.K109= | Silent (SNP) | VAF 101/171 reads (59%) | catalogued as COSV61529228; called by muse, mutect2, varscan2
- TPK1 | c.165C>A p.I55= | Silent (SNP) | VAF 82/592 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.74838T>G p.L24946= (on ENST00000591111; = p.L17522= on NM_003319.4) | Silent (SNP) | VAF 29/202 reads (14%) | called by muse, mutect2, varscan2
- WDR24 | c.1896C>T p.R632= (on ENST00000248142; = p.R502= on NM_032259.4) | Silent (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.576C>T p.A192= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs756008165, COSV56602692, COSV56604494; called by muse, mutect2, varscan2
- ZSCAN1 | c.1155C>T p.C385= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs767219026, COSV56603891, COSV56607266; called by muse, mutect2, varscan2
- ABTB2 | c.*543C>T | 3'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- AC093827.5 | c.*264A>T | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- ACADL | c.603+131T>A | Intron (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- ADAMTS2 | c.*2147C>T | 3'UTR (SNP) | VAF 65/111 reads (59%) | catalogued as rs886060484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRB1 | c.-139G>T | 5'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- ADIPOR2 | c.*1958G>C | 3'UTR (SNP) | VAF 75/125 reads (60%) | called by muse, mutect2, varscan2
- AGBL2 | c.-9A>G | 5'UTR (SNP) | VAF 30/244 reads (12%) | called by muse, mutect2, varscan2
- ALDH1L2 | c.*1367C>T | 3'UTR (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- AP000679.1 | n.506A>T | RNA (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- AP4E1 | c.*32A>G | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- APAF1 | c.*1790G>A | 3'UTR (SNP) | VAF 26/157 reads (17%) | catalogued as rs1458875269, COSV59120827; called by muse, mutect2, varscan2
- APBA2 | c.*354C>T | 3'UTR (SNP) | VAF 37/187 reads (20%) | catalogued as rs1172326917; called by muse, mutect2, varscan2
- APP | c.*395G>C | 3'UTR (SNP) | VAF 23/164 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*2909T>C | 3'UTR (SNP) | VAF 15/59 reads (25%) | catalogued as rs906759584; called by muse, mutect2, varscan2
- ASPH | c.976+12031G>A | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- ASRGL1 | c.*671A>G | 3'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- ATP2B2 | chr3:10325979 C>A | 3'Flank (SNP) | VAF 11/68 reads (16%) | called by mutect2, varscan2
- ATP6V0E2 | c.*556G>C | 3'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- BCL2L1 | c.*1180T>G | 3'UTR (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- BMP1 | c.2108-473G>C | Intron (SNP) | VAF 12/63 reads (19%) | catalogued as rs909530075, COSV100109008; called by muse, mutect2, varscan2
- CACNA1E | c.*1334G>A | 3'UTR (SNP) | VAF 75/159 reads (47%) | called by muse, mutect2, varscan2
- CACNB4 | c.*3857C>A | 3'UTR (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- CACNB4 | c.619-36C>A | Intron (SNP) | VAF 15/108 reads (14%) | catalogued as COSV99137762; called by muse, mutect2, varscan2
- CACNG6 | c.*99T>A | 3'UTR (SNP) | VAF 83/601 reads (14%) | called by muse, mutect2, varscan2
- CASP4 | c.372+54C>T | Intron (SNP) | VAF 30/112 reads (27%) | catalogued as COSV67744436; called by muse, mutect2, varscan2
- CCDC69 | c.-106C>T | 5'UTR (SNP) | VAF 12/100 reads (12%) | catalogued as rs574845656; called by muse, mutect2, varscan2
- CCNI2 | c.*954G>A | 3'UTR (SNP) | VAF 21/29 reads (72%) | called by muse, mutect2, varscan2
- CD276 | c.-48G>A | 5'UTR (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- CELSR1 | c.7952+112G>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- CERT1 | c.-99del | 5'UTR (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- CFAP46 | chr10:132942767 G>T | 5'Flank (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- CFHR5 | c.*521C>G | 3'UTR (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- CHD7 | c.-83G>A | 5'UTR (SNP) | VAF 33/45 reads (73%) | called by muse, mutect2, varscan2
- CLIP2 | c.*968G>A | 3'UTR (SNP) | VAF 26/142 reads (18%) | catalogued as rs770665546; called by muse, mutect2, varscan2
- CMC1 | chr3:28241606 C>T | 5'Flank (SNP) | VAF 16/91 reads (18%) | catalogued as rs1196504692; called by muse, mutect2, varscan2
- CMC1 | c.*1080T>C | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- CPEB4 | c.*2733A>G | 3'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- CSPP1 | c.3077-1209C>T | Intron (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- CYP11B1 | c.954+166G>T | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2
- DDX11 | c.880+51C>T | Intron (SNP) | VAF 8/64 reads (13%) | catalogued as rs369150903; called by muse, mutect2, varscan2
- DGKD | c.*825G>A | 3'UTR (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- DLG2 | c.205-20930C>A | Intron (SNP) | VAF 13/98 reads (13%) | catalogued as rs1288124247; called by muse, mutect2, varscan2
- DOCK5 | c.*2597A>G | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- DPPA4 | c.*845A>T | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- DST | c.4297-3764T>C | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- DTNA | c.1094+1465G>T | Intron (SNP) | VAF 57/227 reads (25%) | called by muse, mutect2, varscan2
- EBF2 | c.*1912_*1913del | 3'UTR (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- EGR3 | c.*241C>T | 3'UTR (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100416261; called by muse, mutect2, varscan2
- EIF4B | c.*1020del | 3'UTR (DEL) | VAF 52/358 reads (15%) | called by mutect2, pindel, varscan2
- ELOVL7 | c.*1039A>T | 3'UTR (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- EN1 | c.*305T>C | 3'UTR (SNP) | VAF 5/55 reads (9%) | catalogued as rs1036995163; called by muse, mutect2
- EPHB4 | c.2484+12G>A | Intron (SNP) | VAF 29/143 reads (20%) | catalogued as rs1230765483; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8559T>G | Intron (SNP) | VAF 26/120 reads (22%) | called by muse, mutect2, varscan2
- FAM135B | c.*1341T>G | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- FAM183BP | n.517C>T | RNA (SNP) | VAF 68/104 reads (65%) | catalogued as rs1160483470; called by muse, mutect2, varscan2
- FAM53C | c.*2191C>G | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- FLT1 | c.*301C>T | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- FNIP2 | c.*3071C>T | 3'UTR (SNP) | VAF 12/64 reads (19%) | catalogued as rs545538836; called by muse, mutect2, varscan2
- FRMD1 | c.461+59C>A | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs1046786786; called by muse, mutect2, varscan2
- FXYD2 | chr11:117818585 C>G | 3'Flank (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- GABRG1 | c.*1539G>A | 3'UTR (SNP) | VAF 35/83 reads (42%) | catalogued as rs763119396; called by muse, mutect2, varscan2
- GALNT17 | c.-410G>A | 5'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- GALNTL5 | c.*122G>A | 3'UTR (SNP) | VAF 50/387 reads (13%) | called by muse, mutect2, varscan2
- GCNT4 | c.*30G>A | 3'UTR (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
- GIGYF2 | c.532+6747G>T | Intron (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
- GINS4 | c.*1917G>A | 3'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as rs560026811; called by muse, mutect2, varscan2
- GLG1 | c.3372+52C>A | Intron (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- GLS | c.1650+3304del | Intron (DEL) | VAF 29/88 reads (33%) | called by mutect2, pindel, varscan2
- GLT8D1 | c.*19A>C | 3'UTR (SNP) | VAF 54/328 reads (16%) | called by muse, mutect2, varscan2
- GLYATL1 | n.343T>A | RNA (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- IK | c.16+180C>T | Intron (SNP) | VAF 46/73 reads (63%) | catalogued as rs1293309423; called by muse, mutect2, varscan2
- IL20 | c.*137G>A | 3'UTR (SNP) | VAF 28/166 reads (17%) | catalogued as rs1241668886; called by muse, mutect2, varscan2
- IL7R | c.*1587G>T | 3'UTR (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2, varscan2
- JAZF1 | c.*967_*968insA | 3'UTR (INS) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- KALRN | c.*107C>A | 3'UTR (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2
- KCNMA1 | c.378+837T>C | Intron (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- KCNV1 | c.*306G>A | 3'UTR (SNP) | VAF 13/66 reads (20%) | catalogued as rs1357214535; called by muse, mutect2, varscan2
- KIAA1549L | c.*2007C>T | 3'UTR (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- KIF26A | chr14:104180799 A>T | 3'Flank (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- KLRC3 | c.*122C>A | 3'UTR (SNP) | VAF 40/406 reads (10%) | catalogued as COSV58672583; called by muse, mutect2
- KPNA1 | c.*3069A>T | 3'UTR (SNP) | VAF 47/174 reads (27%) | called by muse, mutect2, varscan2
- KRBOX1 | c.-47+816A>C | Intron (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- LHPP | c.*671C>T | 3'UTR (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- LIAS | chr4:39459085 C>T | 5'Flank (SNP) | VAF 12/250 reads (5%) | catalogued as rs1285907400; called by muse, mutect2
- LILRB1 | c.-127G>T | 5'UTR (SNP) | VAF 40/270 reads (15%) | called by muse, mutect2, varscan2
- LIMK1 | c.1411-83T>C | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- LINC02724 | n.476C>G | RNA (SNP) | VAF 28/212 reads (13%) | called by muse, mutect2, varscan2
- LPAR6 | c.-492G>C | 5'UTR (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- LTB | c.163-57G>A | Intron (SNP) | VAF 155/260 reads (60%) | catalogued as rs553997400; called by muse, varscan2
- LTB | c.163-58G>A | Intron (SNP) | VAF 154/261 reads (59%) | called by muse, varscan2
- LTB | c.163-59G>A | Intron (SNP) | VAF 156/265 reads (59%) | catalogued as rs932738246; called by muse, varscan2
- MACROD2 | chr20:13995499 C>A | 5'Flank (SNP) | VAF 10/24 reads (42%) | catalogued as rs886235857; called by muse, mutect2, varscan2
- MAP2K3 | c.-27del | 5'UTR (DEL) | VAF 23/103 reads (22%) | called by mutect2, pindel, varscan2
- MARCHF5 | c.-259C>A | 5'UTR (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- MAST4 | c.*1964A>C | 3'UTR (SNP) | VAF 63/97 reads (65%) | called by muse, mutect2, varscan2
- MCHR2 | c.*348C>A | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- MEOX2 | c.*497G>T | 3'UTR (SNP) | VAF 17/124 reads (14%) | catalogued as rs955462979; called by muse, mutect2, varscan2
- MIPOL1 | c.*4073del | 3'UTR (DEL) | VAF 19/41 reads (46%) | called by mutect2, pindel, varscan2
- MIR323A | n.35C>T | RNA (SNP) | VAF 10/12 reads (83%) | catalogued as rs745701252; called by muse, mutect2, varscan2
- MIR4435-1 | chr2:87629626 C>G | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- MIR4510 | n.16T>G | RNA (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- MKNK1 | c.-2-2582G>T | Intron (SNP) | VAF 170/368 reads (46%) | called by mutect2, varscan2
- MRPL39 | c.969+1055C>A | Intron (SNP) | VAF 16/101 reads (16%) | catalogued as COSV56261324; called by muse, mutect2, varscan2
- MS4A7 | c.*957dup | 3'UTR (INS) | VAF 22/74 reads (30%) | catalogued as rs983417190; called by mutect2, varscan2
- NANS | c.-64G>T | 5'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- NDUFS7 | c.*54T>C | 3'UTR (SNP) | VAF 6/117 reads (5%) | called by muse, mutect2
- NOM1 | c.*2585A>T | 3'UTR (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- NOX5 | c.*1262G>A | 3'UTR (SNP) | VAF 47/183 reads (26%) | called by muse, mutect2, varscan2
- NOX5 | c.*1263C>G | 3'UTR (SNP) | VAF 47/182 reads (26%) | catalogued as rs1429241574; called by muse, mutect2, varscan2
- NSUN2 | c.*517T>G | 3'UTR (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- NTRK2 | c.1397-55802T>C | Intron (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- NTRK3 | chr15:87875175 A>T | 3'Flank (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- ORMDL3 | c.*95A>T | 3'UTR (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- PAIP1 | c.-164C>A | 5'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- PAQR9 | chr3:142949621 C>T | 3'Flank (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- PAX1 | c.*548G>C | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- PDCD1LG2 | c.*904T>A | 3'UTR (SNP) | VAF 19/61 reads (31%) | catalogued as rs551159973; called by muse, mutect2, varscan2
- PDE2A | c.704-48C>T | Intron (SNP) | VAF 8/50 reads (16%) | catalogued as rs1324867718; called by muse, mutect2, varscan2
- PDIA4 | c.-202G>A | 5'UTR (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- PEBP1 | c.*558G>T | 3'UTR (SNP) | VAF 12/88 reads (14%) | called by mutect2, varscan2
- PEDS1 | c.*710A>G | 3'UTR (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- PEDS1 | c.*709C>A | 3'UTR (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- PGAP1 | c.*1231T>C | 3'UTR (SNP) | VAF 6/37 reads (16%) | called by mutect2, varscan2
- PGR | c.*1683C>A | 3'UTR (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- PIFO | c.*91C>T | 3'UTR (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1526G>A | RNA (SNP) | VAF 44/248 reads (18%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*4936A>C | 3'UTR (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- PPP4R2 | c.*2995C>T | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- PPP6R1 | c.-6-144G>T | Intron (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- PRKCG | c.-6G>T | 5'UTR (SNP) | VAF 46/448 reads (10%) | called by muse, mutect2, varscan2
- PRR32 | c.*9A>T | 3'UTR (SNP) | VAF 141/218 reads (65%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+4609A>T | Intron (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- RERG | c.61+169T>A | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- RFK | c.337+352C>T | Intron (SNP) | VAF 15/174 reads (9%) | called by muse, mutect2
- RHOBTB1 | c.*434G>A | 3'UTR (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.2182G>A | RNA (SNP) | VAF 28/503 reads (6%) | called by muse, mutect2
- SEPTIN1 | chr16:30378117 G>C | 3'Flank (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- SHLD1 | c.*339G>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- SLC25A21 | chr14:37173616 T>G | 5'Flank (SNP) | VAF 24/47 reads (51%) | catalogued as rs1165924999; called by muse, mutect2, varscan2
- SLC31A1 | c.*1860G>A | 3'UTR (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- SLC45A4 | c.*1810C>T | 3'UTR (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- SMIM13 | chr6:11137552 ins C | 3'Flank (INS) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- SPART | c.*817_*818insT | 3'UTR (INS) | VAF 21/31 reads (68%) | catalogued as rs1044316532; called by mutect2, pindel, varscan2
- SPATC1L | c.*103C>G | 3'UTR (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- SRBD1 | c.*387C>T | 3'UTR (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- SRC | c.*131C>A | 3'UTR (SNP) | VAF 4/33 reads (12%) | catalogued as rs971403330; called by muse, mutect2, varscan2
- SRGAP1 | c.*596C>T | 3'UTR (SNP) | VAF 57/94 reads (61%) | catalogued as rs751556545; called by muse, mutect2, varscan2
- SRGAP3 | c.*3968T>G | 3'UTR (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.14112T>A | RNA (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*78A>G | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2
- STAT3 | c.*113A>G | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, varscan2
- TBC1D1 | c.*796T>A | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as COSV54726267; called by muse, varscan2
- THBD | c.*1809C>G | 3'UTR (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- TIMM50 | chr19:39480628 C>T | 5'Flank (SNP) | VAF 22/190 reads (12%) | catalogued as COSV100068123; called by muse, varscan2
- TMEM129 | c.*629A>G | 3'UTR (SNP) | VAF 52/128 reads (41%) | called by muse, mutect2, varscan2
- TMEM132B | c.*1234G>A | 3'UTR (SNP) | VAF 43/188 reads (23%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975246 G>A | 5'Flank (SNP) | VAF 67/69 reads (97%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.*970G>T | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- TOX4 | chr14:21477132 C>T | 5'Flank (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- TRAPPC3L | c.-126A>G | 5'UTR (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- TSPAN5 | c.*1718C>T | 3'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- UNC5D | c.*2415C>T | 3'UTR (SNP) | VAF 56/297 reads (19%) | catalogued as rs865934777; called by muse, varscan2
- USB1 | c.*929C>T | 3'UTR (SNP) | VAF 33/50 reads (66%) | called by muse, mutect2, varscan2
- WIPF2 | c.*1582G>T | 3'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- WNT7A | c.*2476A>G | 3'UTR (SNP) | VAF 39/58 reads (67%) | called by muse, mutect2, varscan2
- XDH | c.*1635T>A | 3'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2
- YAF2 | c.*1668_*1670delinsGA | 3'UTR (DEL) | VAF 22/29 reads (76%) | called by pindel, varscan2*
- YBX1 | c.167-135A>G | Intron (SNP) | VAF 12/43 reads (28%) | called by muse, varscan2
- ZNF429 | c.-6C>A | 5'UTR (SNP) | VAF 30/239 reads (13%) | called by muse, varscan2
- ZNF474 | c.-56C>G | 5'UTR (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- ZNF493 | chr19:21427315 T>A | 3'Flank (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- ZNF566 | chr19:36489717 C>T | 5'Flank (SNP) | VAF 19/197 reads (10%) | catalogued as rs908336425, COSV101091273; called by muse, mutect2
- ZNF583 | chr19:56426952 A>G | 3'Flank (SNP) | VAF 34/184 reads (18%) | called by muse, varscan2
